Gene-level copy-number profile of tumor specimen HCM-CSHL-0091-C25-01A from HCMI case HCM-CSHL-0091-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.1 years (23,060 days).
Specimen HCM-CSHL-0091-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 99e23e49-4119-4ff2-95dc-9a5ee1845af1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0091-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/ee28ae01-9c45-4053-b54b-a3dc782cff24

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 12; copy number 2: 16,314; copy number 3: 66; copy number 4: 33,947; copy number 5: 876; copy number 6: 7,136; copy number 7: 2; copy number 9: 21.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–23,438,700, 14 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr11:4,233,288–4,288,083, 4 genes: SSU72P5, SSU72P2, SSU72P6, SSU72P4.
- chr17:18,450,244–18,506,313, 6 genes (within-gene range 0–2): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr18:50,968,019–51,218,333, 4 genes (within-gene range 0–2): AC091551.1, SMAD4, SRSF10P1, MEX3C.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 21 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,508,806, 3 genes, copy number 9: AC119751.3, ANKRD20A17P, AC119751.5.
- chr22:20,394,115–20,698,938, 18 genes, copy number 9 (within-gene range 6–9): ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
